Somatic mutation profile of tumor specimen TARGET-30-PASXIE-01A (aliquot TARGET-30-PASXIE-01A-01D) from TARGET case TARGET-30-PASXIE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.3 years (837 days).
Specimen TARGET-30-PASXIE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e41fbef8-510f-4994-9a19-082d76a57aa7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASXIE-10A (Blood Derived Normal), aliquot TARGET-30-PASXIE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f041fc2-d06f-4695-9aeb-515303ae74a2

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.3778G>A p.V1260M | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs760680707, COSV54027797; called by muse, mutect2, varscan2
- ABCB11 | c.2965C>A p.Q989K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as COSV55592740; called by muse, mutect2, varscan2
- ATP10A | c.1880G>T p.S627I | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV63518342; called by muse, mutect2, varscan2
- CENPF | c.6736G>T p.A2246S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.381); catalogued as COSV65275498; called by muse, mutect2, varscan2
- DGKG | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV53966145; called by muse, mutect2, varscan2
- FAM71B | c.1162G>T p.E388* | Nonsense Mutation (SNP) | VAF 224/550 reads (41%) | catalogued as COSV57229383; called by muse, mutect2, varscan2
- INPP5F | c.2528T>C p.V843A | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV62821720; called by muse, mutect2, varscan2
- IRF4 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 117/186 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66705317; called by muse, mutect2, varscan2
- KIAA1109 | c.5307G>A p.M1769I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); catalogued as COSV52676011; called by muse, mutect2, varscan2
- LRP1B | c.9743G>C p.R3248T | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT tolerated (0.33); PolyPhen benign (0.081); catalogued as COSV67228799; called by muse, mutect2, varscan2
- MON2 | c.907G>T p.E303* | Nonsense Mutation (SNP) | VAF 34/161 reads (21%) | catalogued as COSV54808386, COSV54813844; called by muse, mutect2, varscan2
- SYCP2L | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs772179531, COSV51653798; called by muse, mutect2
- TAFA3 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV62624972; called by muse, mutect2, varscan2
- TUBA1B | c.1337A>T p.E446V | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV60137228; called by muse, mutect2, varscan2
- UGT2B11 | c.911T>C p.V304A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV71423466; called by muse, mutect2, varscan2
- ZFP91 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100284776, COSV60159271; called by muse, mutect2, varscan2
- ZNF226 | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as COSV56196798; called by muse, mutect2, varscan2
- GRIK4 | c.1771_1787del p.Y591Pfs*58 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel
- ADGRG4 | c.5178A>T p.L1726= | Silent (SNP) | VAF 38/38 reads (100%) | catalogued as COSV54957858; called by muse, mutect2, varscan2
- ARSJ | c.648G>T p.G216= | Silent (SNP) | VAF 8/199 reads (4%) | called by muse, mutect2
- ITGA5 | c.450C>A p.G150= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV53218200; called by muse, mutect2, varscan2
- NAV2 | c.6729C>A p.L2243= (on ENST00000396087 / NM_001244963.2; = p.L2184= on NM_145117.5) | Silent (SNP) | VAF 53/85 reads (62%) | catalogued as COSV60660051; called by muse, mutect2, varscan2
- MIR424 | n.38C>A | RNA (SNP) | VAF 10/10 reads (100%) | called by muse, mutect2, varscan2
